Somatic mutation profile of tumor specimen TCGA-B0-4712-01A (aliquot TCGA-B0-4712-01A-01D-1501-10) from TCGA case TCGA-B0-4712, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 76.9 years (28,095 days).
Specimen TCGA-B0-4712-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8b257db-407b-4977-bd28-64d63cb39646.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4712-11A (Solid Tissue Normal), aliquot TCGA-B0-4712-11A-02D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58a652c0-d647-46c2-bc4c-684cd4221a30

The open-access MAF lists 93 somatic variants for this specimen: 75 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 65, Silent 18, Frame Shift Del 5, Splice Site 2, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN2A | c.2695G>A p.G899S | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796053120, COSV51839772; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRE3 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs200966967, COSV53729578; called by muse, mutect2, varscan2
- ARGFX | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 82/284 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as rs540135129, COSV57682242; called by muse, varscan2
- ATP2C1 | c.2734A>G p.T912A | Missense Mutation (SNP) | VAF 28/854 reads (3%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV60755866; called by muse, mutect2
- ATRNL1 | c.428G>C p.S143T | Missense Mutation (SNP) | VAF 100/454 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV61803410; called by muse, mutect2, varscan2
- B3GNT2 | c.779A>G p.N260S | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.113); catalogued as COSV57344606; called by muse, mutect2, varscan2
- C20orf194 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV52695413; called by muse, mutect2
- CCDC171 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.292); catalogued as rs759526744, COSV104399983, COSV52640867; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3125A>T p.D1042V | Missense Mutation (SNP) | VAF 191/431 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as COSV62574027; called by muse, mutect2, varscan2
- CDX4 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV65171633; called by muse, mutect2, varscan2
- CFLAR | c.1028A>G p.D343G | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58580075; called by muse, mutect2, varscan2
- CHD3 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.721); catalogued as rs768307299, COSV57873257, COSV57874790; called by muse, mutect2, varscan2
- CHSY3 | c.1857G>C p.K619N | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV100518401, COSV59276872; called by muse, mutect2, varscan2
- COL22A1 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV57335306; called by muse, mutect2
- COL24A1 | c.3335G>C p.R1112T | Missense Mutation (SNP) | VAF 42/295 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as rs752726747, COSV65305634, COSV65306565; called by muse, mutect2, varscan2
- COL6A6 | c.6282C>G p.S2094R | Missense Mutation (SNP) | VAF 101/318 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.661); catalogued as COSV62024195; called by mutect2, varscan2
- CSF1R | c.1200C>A p.Y400* | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | catalogued as COSV53830085, COSV53834260; called by muse, mutect2
- CSMD1 | c.2435C>T p.T812I (on ENST00000520002; = p.T811I on NM_033225.6) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.806); catalogued as rs373861459; called by muse, mutect2, varscan2
- DENND2C | c.1496T>C p.L499P (on ENST00000393274 / NM_001256404.2; = p.L442P on NM_198459.4) | Missense Mutation (SNP) | VAF 46/403 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV67921521; called by muse, mutect2, varscan2
- DHX57 | c.573G>T p.R191S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.995); catalogued as rs1283783635, COSV54884897; called by muse, varscan2
- DLL4 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs1437981675, COSV51062200; called by muse, mutect2, varscan2
- DOCK9 | c.3938T>A p.M1313K (on ENST00000376460 / NM_001366676.2; = p.M1314K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/377 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV59627968; called by muse, mutect2, varscan2
- EMILIN2 | c.1583C>G p.S528* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV54423327; called by muse, mutect2, varscan2
- FBXO34 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58254388; called by muse, mutect2, varscan2
- FNIP1 | c.891G>C p.L297F | Missense Mutation (SNP) | VAF 43/352 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV57195825; called by muse, mutect2, varscan2
- FRYL | c.7413C>G p.C2471W | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV51946250; called by muse, mutect2, varscan2
- GLYAT | c.575G>T p.R192M | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53539226; called by muse, mutect2, varscan2
- GRWD1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV53518583; called by muse, mutect2, varscan2
- HECW2 | c.3989G>T p.R1330L | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99649323; called by muse, mutect2
- HIRIP3 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs761437806, COSV54228973; called by muse, mutect2, varscan2
- HTRA3 | c.668A>G p.D223G | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV56470897; called by muse, mutect2
- IGHV4-34 | c.219G>T p.W73C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs587661087; called by muse, varscan2
- IL33 | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV67342959, COSV67343082; called by muse, mutect2, varscan2
- KDR | c.1367T>G p.I456S | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV55764250; called by muse, varscan2
- LILRB4 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54404881; called by muse, mutect2, varscan2
- LRRC4 | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs531914482, COSV50813856; called by muse, mutect2, varscan2
- MEIOC | c.2095T>G p.S699A | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV63439984; called by muse, mutect2, varscan2
- MRPL32 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 117/379 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56237636; called by muse, mutect2, varscan2
- MS4A6E | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 92/607 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV55726683; called by muse, mutect2
- MTA2 | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.033); catalogued as rs139421444, COSV99545375; called by muse, mutect2, varscan2
- MYLK | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60609652; called by muse, mutect2, varscan2
- NCL | c.1443G>C p.W481C | Missense Mutation (SNP) | VAF 59/490 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as rs746763092, COSV59545716; called by muse, mutect2, varscan2
- NLRC5 | c.2429T>G p.L810R | Missense Mutation (SNP) | VAF 83/294 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52654537; called by muse, mutect2
- NT5DC3 | c.220T>G p.S74A | Missense Mutation (SNP) | VAF 93/302 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV67321710; called by muse, mutect2, varscan2
- OR4N2 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.619); catalogued as COSV60051284; called by muse, mutect2
- P2RY12 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56377649; called by muse, mutect2, varscan2
- PI4KA | c.191T>G p.F64C | Missense Mutation (SNP) | VAF 57/331 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.235); catalogued as COSV55410242; called by muse, mutect2, varscan2
- PRKAR2B | c.1124C>G p.A375G | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV55924575; called by muse, mutect2, varscan2
- RALGAPB | c.4148C>A p.T1383K | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.055); catalogued as COSV53437283; called by muse, mutect2
- RAP1GDS1 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 71/350 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV52786913; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1529C>G p.A510G | Missense Mutation (SNP) | VAF 70/346 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52786924, COSV52793098; called by muse, mutect2, varscan2
- REST | c.2432C>T p.S811F | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV58360474; called by muse, mutect2, varscan2
- SLC17A6 | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV54136018; called by muse, mutect2, varscan2
- SLC17A8 | c.1727C>T p.T576I | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV60123639; called by muse, mutect2, varscan2
- SLC6A12 | c.70A>G p.K24E | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV62885006; called by muse, mutect2, varscan2
- SMC2 | c.970C>A p.L324M | Missense Mutation (SNP) | VAF 77/387 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.213); catalogued as COSV53957698; called by muse, mutect2, varscan2
- STARD13 | c.2845C>A p.P949T (on ENST00000336934 / NM_001243476.3; = p.P831T on NM_052851.3) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs752351561, COSV55230466; called by muse, mutect2
- SUGT1 | c.97-1G>C p.X33_splice | Splice Site (SNP) | VAF 72/342 reads (21%) | catalogued as COSV59421830; called by muse, mutect2
- TADA1 | c.330+2T>A p.X110_splice | Splice Site (SNP) | VAF 98/293 reads (33%) | catalogued as COSV63310219; called by muse, mutect2, varscan2
- TAF2 | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65418001; called by muse, mutect2, varscan2
- TNPO3 | c.2609G>T p.R870L | Missense Mutation (SNP) | VAF 47/371 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as rs188168905, COSV55280870; called by muse, mutect2, varscan2
- TPRG1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV61464918; called by muse, mutect2
- TRPV1 | c.1406del p.T469Mfs*15 | Frame Shift Del (DEL) | VAF 30/185 reads (16%) | catalogued as CM163259, COSV51521868; called by mutect2, varscan2
- TSC2 | c.1254G>T p.R418S | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767670580, COSV54763759; called by muse, mutect2, varscan2
- TSPAN3 | c.152T>A p.L51H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV51214854; called by muse, mutect2
- UHRF1BP1L | c.1250A>T p.K417I | Missense Mutation (SNP) | VAF 207/662 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV54436942; called by muse, mutect2, varscan2
- UTP15 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 94/620 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57140829, COSV99706978, COSV99707055; called by muse, mutect2, varscan2
- VHL | c.563T>G p.L188R | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD962181, CM114581, CM951299, CM982013, COSV56546651, COSV56549626, COSV56559142, COSV56568527; called by muse, mutect2
- ZC3H12B | c.658G>C p.D220H | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59047719; called by muse, mutect2
- ZNF208 | c.200G>C p.R67T | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV68104821; called by muse, mutect2, varscan2
- ARFGEF2 | c.2105_2111del p.R702Tfs*4 | Frame Shift Del (DEL) | VAF 99/364 reads (27%) | called by mutect2, pindel, varscan2
- NRBF2 | c.192del p.H64Qfs*2 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- OSBPL3 | c.2581del p.D861Tfs*4 | Frame Shift Del (DEL) | VAF 82/337 reads (24%) | called by mutect2, pindel, varscan2
- PBRM1 | c.998del p.N333Ifs*29 | Frame Shift Del (DEL) | VAF 91/257 reads (35%) | called by mutect2, pindel, varscan2
- SOX5 | c.1767_1769del p.I589_L590delinsM | In Frame Del (DEL) | VAF 55/437 reads (13%) | called by mutect2, pindel, varscan2
- CES4A | c.243T>C p.A81= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV58653210; called by muse, mutect2, varscan2
- DIP2C | c.3426C>A p.S1142= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV55156657; called by muse, mutect2, varscan2
- ERICH3 | c.567C>A p.T189= | Silent (SNP) | VAF 76/480 reads (16%) | catalogued as COSV58605762; called by mutect2, varscan2
- GOLGB1 | c.6651T>C p.D2217= | Silent (SNP) | VAF 193/625 reads (31%) | catalogued as COSV61465418; called by muse, mutect2, varscan2
- HOGA1 | c.72C>T p.V24= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV53968142; called by muse, mutect2, varscan2
- LONP2 | c.1005C>T p.A335= | Silent (SNP) | VAF 29/380 reads (8%) | catalogued as COSV53522216; called by muse, mutect2
- LRP2 | c.11247A>G p.S3749= | Silent (SNP) | VAF 74/246 reads (30%) | catalogued as rs958306136, COSV55551764; called by muse, mutect2
- NSD1 | c.1290G>A p.Q430= | Silent (SNP) | VAF 59/341 reads (17%) | catalogued as rs535674820, COSV61775712; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUSAP1 | c.1272G>A p.E424= | Silent (SNP) | VAF 32/566 reads (6%) | catalogued as COSV52971086; called by muse, mutect2
- OR51T1 | c.588C>T p.I196= | Silent (SNP) | VAF 52/322 reads (16%) | catalogued as COSV59025196; called by muse, mutect2, varscan2
- PLD5 | c.1398C>T p.G466= (on ENST00000442594; = p.G404= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/399 reads (11%) | catalogued as COSV59144303; called by muse, mutect2, varscan2
- PRPF3 | c.1272C>T p.L424= | Silent (SNP) | VAF 174/512 reads (34%) | catalogued as rs1363962387, COSV61394040, COSV61394697; called by muse, mutect2, varscan2
- RALGAPA2 | c.4278G>T p.L1426= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as COSV52496368; called by muse, mutect2
- SLC16A4 | c.723T>G p.T241= | Silent (SNP) | VAF 125/711 reads (18%) | catalogued as COSV63916483, COSV63917583; called by muse, mutect2, varscan2
- SPRTN | c.1446A>G p.K482= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV50478093; called by muse, mutect2
- TTI2 | c.1428C>G p.L476= | Silent (SNP) | VAF 10/234 reads (4%) | catalogued as rs1475716906, COSV62452494; called by muse, mutect2
- TTLL3 | c.1503T>C p.Y501= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs1159018044, COSV59614271; called by muse, mutect2, varscan2
- ZNF544 | c.297T>C p.A99= | Silent (SNP) | VAF 67/190 reads (35%) | catalogued as rs756031079, COSV54135805; called by muse, mutect2, varscan2
